Somatic mutation profile of tumor specimen 0DCFVU from CCDI case PBBKSG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 17.3 years (6,337 days).
Specimen 0DCFVU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2c99029-18e9-474a-97a8-4d37b551115b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCFVO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a982cd-e143-4d39-b3c1-81e7c3103a60

The open-access MAF lists 40 somatic variants for this specimen: 15 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 15, Missense Mutation 10, Intron 8, Splice Region 2, 3'UTR 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 91/399 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 198/699 reads (28%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.378C>G p.Y126* | Nonsense Mutation (SNP) | VAF 205/617 reads (33%) | hotspot (GDC flag); catalogued as rs1567554500, CM1414507, COSV52662583, COSV52757878, COSV52964885, COSV53125652; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DUSP22 | c.510C>T p.A170= | Splice Region (SNP) | VAF 112/893 reads (13%) | catalogued as rs151089035; called by muse, mutect2, varscan2
- GOLGA8Q | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 87/847 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1354435628; called by muse, varscan2
- HKDC1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 60/774 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs200115968; called by muse, mutect2
- MYH4 | c.348C>T p.Y116= | Splice Region (SNP) | VAF 221/763 reads (29%) | catalogued as rs750137859, COSV55118524; called by muse, mutect2, varscan2
- PDGFRA | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 2222/2959 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57272357; called by muse, mutect2, varscan2
- RALGAPA1 | c.4280A>G p.N1427S | Missense Mutation (SNP) | VAF 161/484 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs749707348, COSV51896509; called by muse, varscan2
- SCPEP1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 132/800 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs138036655; called by muse, mutect2, varscan2
- STAMBP | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 84/516 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1467258991; called by muse, mutect2, varscan2
- ZIM3 | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as rs1040660154; called by muse, mutect2, varscan2
- CCR4 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- FAM161A | c.1093del p.Y365Mfs*9 | Frame Shift Del (DEL) | VAF 230/950 reads (24%) | called by mutect2, pindel, varscan2
- ZNF358 | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 71/453 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- CPNE7 | c.534C>T p.G178= | Silent (SNP) | VAF 142/962 reads (15%) | catalogued as rs749103321; called by muse, mutect2, varscan2
- CYP2C19 | c.1335G>C p.L445= | Silent (SNP) | VAF 178/509 reads (35%) | called by muse, mutect2, varscan2
- DBN1 | c.1725G>A p.P575= | Silent (SNP) | VAF 101/728 reads (14%) | catalogued as rs138973815; called by muse, mutect2, varscan2
- FOXE1 | c.384G>A p.A128= | Silent (SNP) | VAF 118/882 reads (13%) | catalogued as COSV64301149; called by muse, mutect2, varscan2
- GNL3L | c.1674C>T p.I558= | Silent (SNP) | VAF 158/997 reads (16%) | called by muse, mutect2, varscan2
- NALCN | c.927C>T p.L309= | Silent (SNP) | VAF 230/771 reads (30%) | catalogued as rs200398810, COSV51957847, COSV99215251; ClinVar: likely benign; called by muse, mutect2, varscan2
- NIFK | c.333T>C p.F111= | Silent (SNP) | VAF 182/575 reads (32%) | called by muse, mutect2, varscan2
- PTPRJ | c.1692C>T p.D564= | Silent (SNP) | VAF 58/503 reads (12%) | catalogued as rs752830587; called by muse, mutect2, varscan2
- SERPINB2 | c.1227C>T p.F409= | Silent (SNP) | VAF 71/480 reads (15%) | catalogued as rs371265633; called by muse, mutect2, varscan2
- SLC5A7 | c.1131C>T p.I377= | Silent (SNP) | VAF 290/784 reads (37%) | catalogued as rs267598829, COSV50890765; called by muse, mutect2, varscan2
- SMOX | c.1506G>A p.P502= | Silent (SNP) | VAF 96/849 reads (11%) | catalogued as rs138385253; called by muse, mutect2, varscan2
- SPRED3 | c.1044C>T p.G348= | Silent (SNP) | VAF 73/575 reads (13%) | called by muse, mutect2, varscan2
- TDRD10 | c.903C>T p.D301= | Silent (SNP) | VAF 156/942 reads (17%) | catalogued as rs770651464; called by muse, mutect2, varscan2
- TTLL2 | c.42G>A p.A14= | Silent (SNP) | VAF 80/894 reads (9%) | catalogued as rs781121523; called by muse, mutect2
- WNT4 | c.897G>A p.T299= | Silent (SNP) | VAF 110/684 reads (16%) | catalogued as rs139205770, COSV51603649; called by muse, mutect2, varscan2
- ADGRB1 | c.*37A>G | 3'UTR (SNP) | VAF 118/367 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.2387-10C>T | Intron (SNP) | VAF 60/362 reads (17%) | called by muse, mutect2, varscan2
- CACTIN | c.1163-27C>T | Intron (SNP) | VAF 32/175 reads (18%) | catalogued as COSV99698986; called by muse, mutect2, varscan2
- CBX7 | c.179+39C>T | Intron (SNP) | VAF 46/300 reads (15%) | catalogued as rs764250660; called by muse, mutect2, varscan2
- GAS8 | c.90+44C>T | Intron (SNP) | VAF 117/440 reads (27%) | catalogued as rs767318404; called by muse, mutect2
- GFRA2 | c.41-40C>T | Intron (SNP) | VAF 29/162 reads (18%) | catalogued as rs1248995640; called by muse, mutect2, varscan2
- LRRD1 | c.*23T>G | 3'UTR (SNP) | VAF 79/336 reads (24%) | called by muse, mutect2, varscan2
- LUC7L2 | c.62-1591_62-1590insATGCCAAGCC | Intron (INS) | VAF 138/418 reads (33%) | called by mutect2, varscan2
- PRR12 | c.51+383G>A | Intron (SNP) | VAF 110/729 reads (15%) | catalogued as rs768246496, COSV55869458; called by muse, mutect2, varscan2
- VPS33B | c.700+94G>A | Intron (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
